Somatic mutation profile of tumor specimen 0DKSZ9 from CCDI case PBBYFB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.9 years (701 days).
Specimen 0DKSZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e38b4f23-e84d-4c73-b209-cfe3c9d599a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79a6f137-5946-4c48-99a8-cba79468f56a

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRB2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 109/536 reads (20%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.569); catalogued as rs551006593; called by muse, mutect2, varscan2
- H2AJ | c.214_215dup p.D73Vfs*8 | Frame Shift Ins (INS) | VAF 214/620 reads (35%) | called by mutect2, pindel, varscan2
- IL1RAPL1 | c.348C>T p.Y116= | Silent (SNP) | VAF 44/314 reads (14%) | catalogued as rs771224987, COSV56243740; called by muse, mutect2, varscan2
- PIDD1 | c.903C>T p.D301= | Silent (SNP) | VAF 158/487 reads (32%) | catalogued as rs373164089; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3796A>G | 3'UTR (SNP) | VAF 20/596 reads (3%) | called by muse, mutect2
